TCGA case TCGA-38-7271 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8214a0d1-5e2d-4a7a-acb1-e5580755db83

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 800 days (2.2 years).

Diagnoses (5)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.4 years (26,440 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 329 days; Days to treatment end: 371 days (1.0 years); Number of cycles: 3; Treatment dose: 324 mg; Prescribed dose: 30; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 329 days; Days to treatment end: 379 days (1.0 years); Treatment dose: 7,000 cGy; Course number: 1; Number of fractions: 23; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation, Cyberknife; Treatment intent type: Palliative; Days to treatment start: 564 days (1.5 years); Days to treatment end: 564 days (1.5 years); Treatment dose: 2,000 cGy; Course number: 2; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Palliative; Days to treatment start: 574 days (1.6 years); Days to treatment end: 574 days (1.6 years); Number of cycles: 1; Treatment dose: 798 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Treatment intent type: Palliative; Days to treatment start: 574 days (1.6 years); Days to treatment end: 623 days (1.7 years); Number of cycles: 2; Treatment dose: 1,760 mg; Prescribed dose: 500; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 633 days (1.7 years); Days to treatment end: 665 days (1.8 years); Treatment dose: 2,500 cGy; Course number: 3; Number of fractions: 14; Treatment anatomic sites: Distant Site.
2. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Laterality: Left; Classification of tumor: Synchronous primary; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 73.2 years (26,744 days); Days to diagnosis: 304 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 73.9 years (27,001 days); Days to diagnosis: 561 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 74.1 years (27,073 days); Days to diagnosis: 633 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Day 304 (post initial treatment): Progression or recurrence: Yes.
- Day 561 (post initial treatment): Progression or recurrence: Yes.
- Day 633 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 800 days (2.2 years); Disease response: With Tumor.

Other clinical attributes
- DLCO (% of predicted): 76; FEV1/FVC after bronchodilator (%): 46; FEV1/FVC before bronchodilator (%): 43; FEV1 after bronchodilator (% of reference): 45; FEV1 before bronchodilator (% of reference): 40.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1971; Tobacco smoking quit year: 1999.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-38-7271-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-38-7271-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 25.
- Sample TCGA-38-7271-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-38-7271-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-38-7271-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Alimta.
- Radiation treatment 1: Radiation type other: Cyber Knife Stereotactic Radiosurgery.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 2: New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 3: New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Treatment outcome at TCGA followup: Progressive Disease.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: IDC.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: 18.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous L breast cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 800 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 800 days; disease-free interval: event (new tumor event after initially disease-free), 304 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 304 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-38-7271-01A-11D-2035-01): tumor purity 0.26, ploidy 2.08, whole-genome doublings 0.
